TCGA case TCGA-FI-A2D2 — Uterine Corpus Endometrial Carcinoma (TCGA-UCEC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Corpus uteri; Tissue source site: Washington University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/46a1fdb9-548d-44d1-ab77-d51d44ac8198

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 66 years; Vital status: Dead; Days to death: 2,352 days (6.4 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 66.4 years (24,260 days); Year of diagnosis: 2008; Method of diagnosis: Biopsy; FIGO stage: Stage IB; FIGO staging edition year: 1988; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 2,352 days (6.4 years).
   Pathology details: Consistent pathology review: Yes; Percent tumor invasion: 33.
   Pathology details: Lymph node involved site: Aortic; Lymph nodes tested: 0.
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes tested: 0.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Days to treatment start: 87 days; Days to treatment end: 191 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Surgery, Open; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Radiation Therapy, NOS; Surgery, NOS, for recurrent disease; Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS), site: Lung, NOS. Age at diagnosis: 71.7 years (26,177 days); Days to diagnosis: 1,917 days (5.2 years); Prior treatment: Yes.

Follow-up (5 entries)
- Days to follow up: 1,095 days (3.0 years); Disease response: Tumor Free.
- Days to follow up: 1,215 days (3.3 years); Disease response: Tumor Free.
- Day 1,917 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Lung, NOS; Days to recurrence: 1,917 days (5.2 years).
- Days to follow up: 2,352 days (6.4 years); Disease response: With Tumor.
- Peritoneal washing results: Negative; Timepoint: Initial Diagnosis.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 166 kg; Height: 168 cm; BMI: 58.8.
- Timepoint category: Prior to Diagnosis; Hormonal replacement therapy status: No; Menopause status: Postmenopausal; Number of pregnancies: 2; Pregnancy outcome: Full Term Birth, NOS; Risk factors: Hypertension.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-FI-A2D2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 70 mg.
  Slide TCGA-FI-A2D2-01A-01-TS1: Section location: Top; Percent tumor cells: 96; Percent tumor nuclei: 98; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 2; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 5.
- Sample TCGA-FI-A2D2-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-FI-A2D2-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: Tumor free; Submitted tumor site: Endometrial; Histologic diagnosis: Mixed serous and endometrioid; Method initial path diagnosis: Office Endometrial Biopsy; Surgical approach at diagnosis: open.
- Follow-up form 1: History menopausal hormone therapy: No, I have never taken menopausal hormone therapy; History tamoxifen use: Never Used; Hypertension diagnosis: Yes; Diabetes diagnosis indicator: No; Pregnancies full term count: 2; History colorectal cancer: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response.
- Follow-up form 2: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome at TCGA followup: Progressive Disease.
- Drug treatment 1: Pharmaceutical therapy drug name: carboplatinum.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 2,352 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 2,352 days; disease-free interval: event (new tumor event after initially disease-free), 1,917 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,917 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-FI-A2D2-01A-11D-A17C-01): tumor purity 0.68, ploidy 3.38, whole-genome doublings 1.
